MMRF case MMRF_1703 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/05609743-ed5e-4e27-8ef7-c404afb0c3c2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.5 years (27,212 days); ISS stage: II; Days to last known disease status: 1,145 days (3.1 years); Days to last follow up: 1,145 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 563 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 164 days; Days to treatment end: 185 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 164 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 598 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 606 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 612 days (1.7 years); Days to treatment end: 787 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -12 (ECOG 1): M Protein 2.14 g/dL; Beta 2 Microglobulin 0.37 µg/mL; Hemoglobin 7.94 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.66 ×10⁹/L; Platelets 277 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.45 mmol/L; Albumin 30 g/L; Total Protein 8.8 g/dL; Glucose 7.59 mmol/L.
- Day 71: M Protein 1.67 g/dL; Beta 2 Microglobulin 0.32 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 5.56 mmol/L.
- Day 164 (ECOG 0): M Protein 1.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.369 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.43 mg/dL; Beta 2 Microglobulin 0.21 µg/mL; Hemoglobin 7.01 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 34 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 276 (ECOG 1): M Protein 0.56 g/dL; Hemoglobin 8.06 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.45 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.89 mmol/L.
- Day 367 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.463 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Hemoglobin 7.87 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 6.33 mmol/L.
- Day 451 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.357 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.44 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 70 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 6.6 mmol/L.
- Day 563 (ECOG 0): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.69 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 6.55 mmol/L.
- Day 647 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.477 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Hemoglobin 7.13 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 738 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.702 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 106 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.16 mmol/L.
- Day 822 (ECOG 1): M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.651 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.59 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 64 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 5.61 mmol/L.
- Day 935 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.739 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Hemoglobin 7.5 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 4.95 mmol/L.
- Day 1,019 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.446 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 10.8 mmol/L.
- Day 1,082 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.64 mg/dL; Hemoglobin 7.56 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 5.8 g/dL; Glucose 7.7 mmol/L.
- Day 1,145 (ECOG 1): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.423 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 5.05 g/L; Beta 2 Microglobulin 0.39 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 5.9 g/dL; Glucose 11.1 mmol/L.

Other clinical attributes
- Day -12: Weight: 90 kg; Height: 178 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1703_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -12 days.
- Sample MMRF_1703_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -12 days.
